Somatic mutation profile of tumor specimen C3L-01460-01 (aliquot CPT0390250006) from CPTAC case C3L-01460, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary renal cell carcinoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 69.8 years (25,493 days).
Specimen C3L-01460-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e3b2e4f-b302-44fc-9426-44d23594a4a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01460-31 (Blood Derived Normal), aliquot CPT0390310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5c62300-7632-47e2-931d-3ac57c761c1d

The open-access MAF lists 88 somatic variants for this specimen: 55 protein-altering or splice-affecting, 19 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 19, Intron 10, Frame Shift Del 5, Splice Region 4, In Frame Del 3, 5'UTR 2, 3'UTR 2, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHCTF1 | c.1229C>G p.S410W (on ENST00000366508; = p.S384W on NM_015446.5) | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1163286976, COSV58246164; called by muse, mutect2, varscan2
- AKAP6 | c.4774C>T p.R1592* | Nonsense Mutation (SNP) | VAF 41/98 reads (42%) | catalogued as rs772048866, COSV99800852; called by muse, mutect2, varscan2
- ELOA | c.1549A>G p.I517V | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.556); catalogued as rs1166113029; called by muse, mutect2, varscan2
- FBXW9 | c.1379A>G p.N460S (on ENST00000587955; = p.N440S on NM_032301.3) | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.798); catalogued as rs756857411; called by muse, mutect2, varscan2
- FGFR1 | c.2357C>G p.S786C (on ENST00000447712 / NM_023110.3; = p.S784C on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775161322; called by muse, mutect2, varscan2
- MTMR6 | c.255_258del p.R86Ifs*82 | Frame Shift Del (DEL) | VAF 41/100 reads (41%) | catalogued as rs747139963; called by mutect2, pindel, varscan2
- RRAGC | c.900-3T>A | Splice Region (SNP) | VAF 40/117 reads (34%) | catalogued as rs1416772892; called by muse, mutect2, varscan2
- SPRY2 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 186/426 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as COSV65701321; called by muse, mutect2, varscan2
- SRSF7 | c.387-3T>C | Splice Region (SNP) | VAF 98/227 reads (43%) | catalogued as rs375887811; called by muse, mutect2, varscan2
- YES1 | c.1077C>A p.F359L | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV100099882; called by muse, mutect2, varscan2
- ZNF197 | c.1061G>C p.G354A | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.033); catalogued as rs778817218; called by muse, mutect2, varscan2
- ZNF546 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1432547382; called by muse, mutect2, varscan2
- BMPR2 | c.1136C>G p.T379S | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- BRD1 | c.574C>A p.R192S | Missense Mutation (SNP) | VAF 95/254 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CATSPERE | c.711T>A p.S237R | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CCNI | c.175T>C p.F59L | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CCPG1 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- DHX58 | c.1168C>G p.Q390E | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- DNAH8 | c.9127C>G p.L3043V | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJC14 | c.1488T>A p.N496K | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ENTPD3 | c.1361del p.N454Ifs*4 | Frame Shift Del (DEL) | VAF 56/163 reads (34%) | called by mutect2, pindel
- EP400 | c.587C>G p.S196* | Nonsense Mutation (SNP) | VAF 93/324 reads (29%) | called by muse, mutect2, varscan2
- FBXO21 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 95/250 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- GPR182 | c.209A>G p.E70G | Missense Mutation (SNP) | VAF 106/264 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- GRK4 | c.406_408del p.E136del (on ENST00000398052 / NM_182982.3; = p.E104del on NM_005307.3) | In Frame Del (DEL) | VAF 23/82 reads (28%) | called by pindel, varscan2
- HIVEP3 | c.2527C>G p.L843V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- KLK2 | c.276del p.S93Afs*11 | Frame Shift Del (DEL) | VAF 96/221 reads (43%) | called by mutect2, pindel*, varscan2
- L3HYPDH | c.162dup p.R55Afs*5 | Frame Shift Ins (INS) | VAF 106/298 reads (36%) | called by mutect2, pindel, varscan2
- OR5M8 | c.63A>C p.E21D | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PER1 | c.2133G>C p.K711N | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PKD1L1 | c.4857A>T p.V1619= | Splice Region (SNP) | VAF 81/311 reads (26%) | called by muse, mutect2, varscan2
- PPARG | c.862G>T p.D288Y (on ENST00000287820 / NM_015869.5; = p.D258Y on NM_005037.7) | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RBPMS | c.*7del | Splice Region (DEL) | VAF 55/154 reads (36%) | called by mutect2, pindel, varscan2
- SAC3D1 | c.808G>C p.G270R | Missense Mutation (SNP) | VAF 112/228 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SBNO2 | c.2831_2832del p.S944Cfs*121 | Frame Shift Del (DEL) | VAF 43/152 reads (28%) | called by mutect2, pindel, varscan2
- SPATA31A6 | c.2260A>T p.N754Y | Missense Mutation (SNP) | VAF 76/462 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- STEAP4 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- TENM4 | c.1961_1975del p.G654_E658del | In Frame Del (DEL) | VAF 36/93 reads (39%) | called by mutect2, pindel, varscan2
- THRAP3 | c.2542T>C p.Y848H | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- TOGARAM1 | c.1895A>G p.D632G | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TPH2 | c.1165-2A>T p.X389_splice | Splice Site (SNP) | VAF 117/312 reads (38%) | called by muse, mutect2, varscan2
- TRAPPC8 | c.1679A>G p.Y560C | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- TRIM29 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TUBB4B | c.932del p.L311Rfs*13 | Frame Shift Del (DEL) | VAF 54/213 reads (25%) | called by mutect2, pindel, varscan2
- TUT4 | c.4115G>T p.C1372F | Missense Mutation (SNP) | VAF 101/240 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TXNDC15 | c.440A>G p.Y147C | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- USP1 | c.2166_2180del p.I724_G728del | In Frame Del (DEL) | VAF 35/92 reads (38%) | called by mutect2, pindel, varscan2
- VEGFD | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 115/134 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ZDBF2 | c.3685G>C p.V1229L | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZIK1 | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZNF20 | c.1151T>G p.I384S | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.223); called by muse, mutect2
- ZNF383 | c.1351A>T p.N451Y | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- ZNF568 | c.359-2A>T p.X120_splice | Splice Site (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- ZNF697 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ZNF81 | c.1530G>C p.R510S | Missense Mutation (SNP) | VAF 77/96 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ATP2B2 | c.3453G>A p.S1151= (on ENST00000352432; = p.S1117= on NM_001330611.3) | Silent (SNP) | VAF 9/187 reads (5%) | catalogued as rs951509551; called by muse, mutect2
- AUP1 | c.1035C>T p.I345= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as rs769522674, COSV57818388; called by muse, mutect2, varscan2
- B3GNT6 | c.168G>C p.A56= | Silent (SNP) | VAF 74/174 reads (43%) | called by muse, mutect2, varscan2
- BIRC6 | c.2248C>A p.R750= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV101427911; called by muse, mutect2, varscan2
- C1orf68 | c.135A>T p.T45= | Silent (SNP) | VAF 139/337 reads (41%) | called by muse, mutect2, varscan2
- DNAJB5 | c.735G>A p.V245= | Silent (SNP) | VAF 55/139 reads (40%) | called by muse, mutect2, varscan2
- EFCAB11 | c.327A>G p.G109= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as rs973300885; called by muse, mutect2, varscan2
- GDF1 | c.1072C>T p.L358= | Silent (SNP) | VAF 171/425 reads (40%) | called by muse, mutect2, varscan2
- HPS4 | c.156G>A p.L52= | Silent (SNP) | VAF 93/232 reads (40%) | catalogued as COSV61104068; called by muse, mutect2, varscan2
- IFNA17 | c.429G>T p.V143= | Silent (SNP) | VAF 125/340 reads (37%) | catalogued as rs1340395652; called by muse, mutect2, varscan2
- ODF2 | c.1848A>G p.Q616= (on ENST00000434106 / NM_153433.2; = p.Q592= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 178/421 reads (42%) | catalogued as rs780074465, COSV63547945; called by muse, mutect2, varscan2
- PGK1 | c.918C>T p.G306= | Silent (SNP) | VAF 15/143 reads (10%) | catalogued as rs1557248255; called by muse, mutect2, varscan2
- POTEJ | c.1908A>G p.K636= | Silent (SNP) | VAF 90/418 reads (22%) | called by muse, mutect2, varscan2
- SELENOP | c.138T>C p.N46= | Silent (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- SLC7A7 | c.1455C>A p.V485= | Silent (SNP) | VAF 84/186 reads (45%) | catalogued as COSV53538249; called by muse, mutect2, varscan2
- SLC8A2 | c.942G>A p.E314= | Silent (SNP) | VAF 16/380 reads (4%) | catalogued as rs1204301539; called by muse, mutect2
- SLFN13 | c.1881T>A p.I627= | Silent (SNP) | VAF 25/151 reads (17%) | called by muse, mutect2, varscan2
- STEAP4 | c.546A>T p.S182= | Silent (SNP) | VAF 33/61 reads (54%) | called by muse, mutect2, varscan2
- SYNE2 | c.15354T>C p.V5118= | Silent (SNP) | VAF 83/209 reads (40%) | catalogued as rs1324430174; called by muse, mutect2, varscan2
- ABCD4 | c.1753-10T>C | Intron (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2, varscan2
- ALKAL2 | c.*32C>A | 3'UTR (SNP) | VAF 50/129 reads (39%) | called by muse, mutect2, varscan2
- ALOX12B | c.650+28G>A | Intron (SNP) | VAF 231/393 reads (59%) | catalogued as rs369676019; called by muse, mutect2, varscan2
- ANXA11 | c.1459-539A>C | Intron (SNP) | VAF 49/132 reads (37%) | called by muse, mutect2, varscan2
- FAM204A | c.543+3822A>G | Intron (SNP) | VAF 53/120 reads (44%) | called by muse, mutect2, varscan2
- KDM2B | c.1048-3403C>T | Intron (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
- MACF1 | c.543+11314A>T | Intron (SNP) | VAF 13/269 reads (5%) | called by muse, mutect2
- MMAB | c.*1311C>A | 3'UTR (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- PGBD2 | c.-25G>C | 5'UTR (SNP) | VAF 12/158 reads (8%) | catalogued as rs1220540679; called by muse, mutect2
- SALL1 | c.77-1259C>G | Intron (SNP) | VAF 61/90 reads (68%) | called by muse, mutect2, varscan2
- SFRP1 | c.623-9811G>T | Intron (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- SLC45A2 | c.1156+76T>C | Intron (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2, varscan2
- WASHC5 | c.-6C>A | 5'UTR (SNP) | VAF 92/247 reads (37%) | catalogued as COSV100572709; called by muse, mutect2, varscan2
- ZNF451 | c.186+2238T>G | Intron (SNP) | VAF 78/151 reads (52%) | called by muse, mutect2, varscan2
